Somatic mutation profile of tumor specimen 0DRQT4 from CCDI case PBCGZE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; Age at diagnosis: 15.9 years (5,791 days).
Specimen 0DRQT4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 024e8202-4325-403d-b805-943cfb0668d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRQSS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6faac4b4-11f0-4064-b901-7b8516fe63db

The open-access MAF lists 102 somatic variants for this specimen: 72 protein-altering or splice-affecting, 14 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 14, Intron 11, Nonsense Mutation 5, 3'UTR 3, Frame Shift Del 2, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2731G>T p.E911* | Nonsense Mutation (SNP) | VAF 173/913 reads (19%) | catalogued as rs398123119, COSV57349858; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 204/914 reads (22%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 268/833 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4943G>A p.R1648H (on ENST00000303395 / NM_001202435.3; = p.R1637H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/1518 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918622, CM000570; ClinVar: not provided / pathogenic; called by muse, mutect2
- AKNAD1 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 50/888 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV62195242; called by muse, mutect2
- APC | c.4466del p.L1489Yfs*18 | Frame Shift Del (DEL) | VAF 195/1000 reads (20%) | catalogued as COSV57327796; called by mutect2, pindel, varscan2
- ARMCX3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 393/1334 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV57870123; called by muse, mutect2, varscan2
- COL1A2 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 146/832 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764327381, COSV51957617; called by muse, mutect2, varscan2
- COL20A1 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 289/645 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.07); catalogued as rs1183558096, COSV100491720; called by muse, mutect2, varscan2
- DNAH10 | c.5496G>T p.Q1832H (on ENST00000409039; = p.Q1771H on NM_207437.3) | Missense Mutation (SNP) | VAF 291/790 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292259; called by muse, mutect2, varscan2
- HHAT | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 202/657 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776106560; called by muse, mutect2, varscan2
- KCNH4 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 202/558 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs537747952, COSV52917718; called by muse, mutect2, varscan2
- LOXL2 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757110393; called by muse, varscan2
- LRRK2 | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 337/1055 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs769535907, COSV54155939; called by muse, mutect2, varscan2
- LSAMP | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 142/704 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.778); catalogued as rs117984283; called by muse, mutect2, varscan2
- MAP7 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176503056; called by muse, mutect2, varscan2
- MDC1 | c.3415C>A p.P1139T | Missense Mutation (SNP) | VAF 199/824 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as COSV64525215; called by muse, mutect2, varscan2
- MMP1 | c.377C>G p.P126R | Missense Mutation (SNP) | VAF 153/655 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV59511665; called by muse, mutect2, varscan2
- OR52E6 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 217/1159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61433390; called by muse, mutect2, varscan2
- PCNT | c.9677C>T p.A3226V | Missense Mutation (SNP) | VAF 45/768 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs879161346; called by muse, mutect2
- PRELID2 | c.7G>T p.V3F | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs553963912; called by muse, mutect2, varscan2
- PRICKLE1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 206/624 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759969939, COSV61547493; called by muse, mutect2, varscan2
- PSG3 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 227/993 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.019); catalogued as rs767985335; called by muse, mutect2, varscan2
- SACS | c.6496C>T p.R2166C | Missense Mutation (SNP) | VAF 433/1068 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs764516788, COSV66538036; called by muse, mutect2, varscan2
- SORCS2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 93/405 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs371760048; called by muse, mutect2, varscan2
- TMPRSS12 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 89/490 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1349206893, COSV68256764; called by muse, mutect2, varscan2
- TP53 | c.102dup p.P36Afs*7 | Frame Shift Ins (INS) | VAF 76/307 reads (25%) | catalogued as COSV52674838; called by mutect2, pindel, varscan2
- UBA1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 72/476 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs782796398; called by muse, mutect2, varscan2
- UGT3A1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 139/661 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as COSV57095281; called by muse, mutect2, varscan2
- ZDHHC8 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs780009061; called by muse, mutect2, varscan2
- ZNF804A | c.1649A>T p.N550I | Missense Mutation (SNP) | VAF 187/1080 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV56475543; called by muse, mutect2
- ABCA12 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 241/1078 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ABCA9 | c.4174C>T p.L1392F | Missense Mutation (SNP) | VAF 108/764 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ACOT8 | c.612A>T p.K204N | Missense Mutation (SNP) | VAF 118/1079 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- AGFG1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 152/724 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AMER1 | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 174/569 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKMY1 | c.2552C>A p.P851H | Missense Mutation (SNP) | VAF 75/358 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ATP8B4 | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 121/629 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- BNC1 | c.1782G>T p.Q594H | Missense Mutation (SNP) | VAF 102/434 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); called by mutect2, varscan2
- C4orf54 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 112/449 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CAPRIN2 | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 41/1189 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.054); called by muse, mutect2
- CEP152 | c.70T>A p.Y24N | Missense Mutation (SNP) | VAF 148/726 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNNM1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- CNTN6 | c.2487T>A p.N829K | Missense Mutation (SNP) | VAF 31/879 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.926); called by muse, mutect2
- COL5A2 | c.3740C>A p.P1247Q | Missense Mutation (SNP) | VAF 120/634 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CRB1 | c.2601T>A p.N867K | Missense Mutation (SNP) | VAF 177/1103 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CTNND2 | c.2632T>G p.W878G | Missense Mutation (SNP) | VAF 142/677 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP4X1 | c.971G>C p.S324T | Missense Mutation (SNP) | VAF 120/690 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- DPP8 | c.1451C>G p.S484C (on ENST00000341861 / NM_001320875.2; = p.S468C on NM_017743.6) | Missense Mutation (SNP) | VAF 80/918 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2
- DPYSL5 | c.947+1G>T p.X316_splice | Splice Site (SNP) | VAF 132/558 reads (24%) | called by muse, mutect2, varscan2
- HAUS7 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 201/510 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HINFP | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HTR1A | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 17/566 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.334); called by muse, mutect2
- IMPG1 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 32/1012 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- ITIH1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 154/711 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KASH5 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 139/711 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNA4 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 25/473 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- KRT71 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 279/737 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LTB4R | c.176A>T p.N59I | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NPBWR2 | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); called by muse, mutect2
- NPY2R | c.193del p.V65* | Frame Shift Del (DEL) | VAF 99/655 reads (15%) | called by mutect2, pindel, varscan2
- PIGQ | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PKHD1L1 | c.2747G>A p.W916* | Nonsense Mutation (SNP) | VAF 30/1004 reads (3%) | called by muse, mutect2
- RELN | c.1180C>A p.H394N | Missense Mutation (SNP) | VAF 178/850 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- RSRC2 | c.203A>T p.K68I | Missense Mutation (SNP) | VAF 106/836 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHC1 | c.1444C>T p.Q482* (on ENST00000368445 / NM_183001.5; = p.Q373* on NM_003029.5) | Nonsense Mutation (SNP) | VAF 75/996 reads (8%) | called by muse, mutect2
- SLC12A7 | c.2923G>C p.D975H | Missense Mutation (SNP) | VAF 39/559 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2
- SLCO1B1 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 83/1172 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- SUPT6H | c.4592G>A p.R1531Q | Missense Mutation (SNP) | VAF 271/727 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- THSD4 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR87 | c.1212C>A p.C404* | Nonsense Mutation (SNP) | VAF 84/408 reads (21%) | called by mutect2, varscan2
- ZNF804B | c.3236C>G p.S1079C | Missense Mutation (SNP) | VAF 62/1380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ACSL6 | c.675C>A p.I225= (on ENST00000379240; = p.I250= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/413 reads (20%) | catalogued as rs1455718255, COSV57299012; called by muse, mutect2, varscan2
- C19orf71 | c.51C>T p.T17= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as rs1253700297; called by muse, mutect2
- CFAP46 | c.363A>G p.G121= | Silent (SNP) | VAF 96/428 reads (22%) | called by muse, mutect2, varscan2
- DNAH5 | c.1125T>C p.N375= | Silent (SNP) | VAF 24/746 reads (3%) | called by muse, mutect2
- FNDC3B | c.909C>T p.S303= | Silent (SNP) | VAF 212/821 reads (26%) | called by muse, mutect2, varscan2
- GPR146 | c.654G>A p.T218= | Silent (SNP) | VAF 56/252 reads (22%) | catalogued as rs767465966, COSV99866367; called by muse, mutect2, varscan2
- GRK2 | c.348G>A p.E116= | Silent (SNP) | VAF 101/451 reads (22%) | catalogued as rs1301886792; called by muse, mutect2, varscan2
- ITGAL | c.117G>A p.P39= | Silent (SNP) | VAF 83/283 reads (29%) | catalogued as rs751180213; called by muse, mutect2, varscan2
- KIF22 | c.1687C>T p.L563= | Silent (SNP) | VAF 124/668 reads (19%) | called by muse, mutect2, varscan2
- MUC17 | c.1035G>A p.P345= | Silent (SNP) | VAF 146/643 reads (23%) | catalogued as rs368047713; called by muse, mutect2, varscan2
- MYO5C | c.3579C>T p.I1193= | Silent (SNP) | VAF 79/896 reads (9%) | catalogued as rs941660860; called by muse, mutect2
- SLC26A9 | c.438G>A p.S146= | Silent (SNP) | VAF 233/630 reads (37%) | catalogued as rs200068898; called by muse, mutect2, varscan2
- SORL1 | c.948G>A p.L316= | Silent (SNP) | VAF 53/574 reads (9%) | called by muse, mutect2
- TK1 | c.558G>A p.R186= | Silent (SNP) | VAF 109/578 reads (19%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3626-821G>C | Intron (SNP) | VAF 8/63 reads (13%) | called by mutect2, varscan2
- ASAP1 | c.2173-64G>T | Intron (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2
- AUP1 | c.339+85A>G | Intron (SNP) | VAF 35/199 reads (18%) | catalogued as rs1447381813; called by muse, mutect2, varscan2
- CACNA1H | c.803+34C>T | Intron (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2, varscan2
- CDC40 | c.728-65G>T | Intron (SNP) | VAF 46/230 reads (20%) | called by mutect2, varscan2
- EML2 | chr19:45641944 G>A | 5'Flank (SNP) | VAF 77/392 reads (20%) | called by muse, mutect2, varscan2
- FSTL3 | c.734-38del | Intron (DEL) | VAF 43/229 reads (19%) | called by mutect2, pindel, varscan2
- FSTL3 | c.734-41C>A | Intron (SNP) | VAF 42/205 reads (20%) | called by mutect2, varscan2
- MLXIPL | c.*80G>T | 3'UTR (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- NACA | c.*21T>A | 3'UTR (SNP) | VAF 145/863 reads (17%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109897G>T | Intron (SNP) | VAF 62/282 reads (22%) | catalogued as rs777054372; ClinVar: uncertain significance; called by mutect2, varscan2
- PPP1R9A | c.2757+630C>T | Intron (SNP) | VAF 148/648 reads (23%) | catalogued as rs76370051; called by muse, mutect2, varscan2
- RBM5 | c.1455+44C>T | Intron (SNP) | VAF 90/433 reads (21%) | catalogued as rs772897383; called by muse, mutect2, varscan2
- SERHL2 | c.731+80G>C | Intron (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2
- TDRD6 | c.-16G>A | 5'UTR (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- WNT8A | c.*311C>T | 3'UTR (SNP) | VAF 63/252 reads (25%) | called by muse, mutect2, varscan2
